Somatic mutation profile of tumor specimen PCProject_0524_T1_WES (aliquot PCProject_0524_T1_WES_1) from CMI case PCProject_0524, project CMI-MPC: Count Me In (CMI): The Metastatic Prostate Cancer (MPC) Project. Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 56.2 years (20,533 days).
Specimen PCProject_0524_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Prostate; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 18f63226-1136-4bab-87a7-a9ac893994a7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen PCProject_0524_SALIVA (DNA), aliquot PCProject_0524_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ca161f82-48c8-4243-9dae-9efcfc27e8df

The open-access MAF lists 45 somatic variants for this specimen: 27 protein-altering or splice-affecting, 10 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 10, RNA 3, Intron 3, Nonsense Mutation 2, Frame Shift Ins 2, Splice Site 1, Frame Shift Del 1, In Frame Del 1, 3'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 71/298 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AGPAT4 | c.619C>T p.R207* | Nonsense Mutation (SNP) | VAF 131/521 reads (25%) | catalogued as rs1454374642, COSV100210802; called by muse, mutect2, varscan2
- BPIFC | c.309C>G p.I103M | Missense Mutation (SNP) | VAF 16/177 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.94); catalogued as rs1321794839; called by muse, mutect2
- DAPP1 | c.124C>T p.R42C | Missense Mutation (SNP) | VAF 48/212 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776332284, COSV99596780; called by muse, mutect2, varscan2
- EGR2 | c.844G>A p.G282R | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.038); catalogued as rs1449637341; called by muse, mutect2, varscan2
- NTRK3 | c.2134C>G p.L712V | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (1); PolyPhen possibly damaging (0.694); catalogued as rs1379390446; called by muse, mutect2
- PES1 | c.1085T>C p.I362T | Missense Mutation (SNP) | VAF 35/168 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs1437231639; called by muse, mutect2, varscan2
- SPON1 | c.151C>G p.Q51E | Missense Mutation (SNP) | VAF 19/374 reads (5%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.655); catalogued as rs1554907679; called by muse, mutect2
- SYNE1 | c.25259G>A p.R8420Q (on ENST00000367255 / NM_182961.4; = p.R8372Q on NM_033071.3) | Missense Mutation (SNP) | VAF 88/430 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs556231915, COSV55084554; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TMEM87A | c.973C>T p.R325C | Missense Mutation (SNP) | VAF 41/147 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1263053146, COSV67746168; called by muse, varscan2
- TPCN1 | c.1822C>T p.R608C | Missense Mutation (SNP) | VAF 79/278 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as rs775946240; called by muse, mutect2, varscan2
- WRAP73 | c.631G>A p.G211S | Missense Mutation (SNP) | VAF 66/245 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1479436241; called by muse, mutect2, varscan2
- HCRT | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.184); called by mutect2, varscan2
- HNRNPL | c.1387C>T p.Q463* | Nonsense Mutation (SNP) | VAF 54/171 reads (32%) | called by muse, mutect2, varscan2
- MRPL24 | c.279+2T>G p.X93_splice | Splice Site (SNP) | VAF 60/215 reads (28%) | called by muse, mutect2, varscan2
- OGA | c.246_248del p.F82_R83delinsL | In Frame Del (DEL) | VAF 19/75 reads (25%) | called by mutect2, pindel, varscan2
- OR10Z1 | c.456del p.Y153Tfs*7 | Frame Shift Del (DEL) | VAF 63/227 reads (28%) | called by mutect2, pindel, varscan2
- PDIA3 | c.998G>C p.G333A | Missense Mutation (SNP) | VAF 27/200 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PFKL | c.1743dup p.V582Rfs*51 | Frame Shift Ins (INS) | VAF 41/189 reads (22%) | called by mutect2, pindel, varscan2
- POLR3A | c.4147G>A p.E1383K | Missense Mutation (SNP) | VAF 99/414 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PTEN | c.867dup p.V290Sfs*8 | Frame Shift Ins (INS) | VAF 84/356 reads (24%) | called by pindel, varscan2
- RAP1B | c.316A>T p.T106S | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.58); PolyPhen benign (0.005); called by mutect2, varscan2
- RC3H2 | c.1505G>T p.S502I | Missense Mutation (SNP) | VAF 53/329 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- SORL1 | c.2449T>G p.L817V | Missense Mutation (SNP) | VAF 49/168 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.587); called by muse, varscan2
- VSIG4 | c.64A>T p.I22F | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); called by mutect2, varscan2
- YME1L1 | c.2011A>G p.T671A (on ENST00000326799 / NM_139312.3; = p.T614A on NM_014263.4) | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ZFAND1 | c.544T>G p.F182V | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- ERBB3 | c.1335C>G p.S445= | Silent (SNP) | VAF 121/521 reads (23%) | catalogued as rs1240009619; called by muse, mutect2, varscan2
- KIF1B | c.1557T>C p.D519= (on ENST00000377086 / NM_001365952.1; = p.D473= on NM_015074.3) | Silent (SNP) | VAF 111/440 reads (25%) | catalogued as rs146364486; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYO18B | c.1212C>T p.N404= | Silent (SNP) | VAF 69/275 reads (25%) | catalogued as rs772481621; called by muse, mutect2, varscan2
- PDE12 | c.420T>C p.D140= | Silent (SNP) | VAF 41/138 reads (30%) | called by mutect2, varscan2
- PHF24 | c.744G>A p.A248= | Silent (SNP) | VAF 95/609 reads (16%) | catalogued as rs756785232, COSV54275288; called by muse, mutect2, varscan2
- PXDNL | c.4026T>C p.D1342= | Silent (SNP) | VAF 57/134 reads (43%) | called by muse, mutect2, varscan2
- SPHK2 | c.1207C>T p.L403= | Silent (SNP) | VAF 57/241 reads (24%) | called by muse, mutect2, varscan2
- TERF1 | c.225C>T p.A75= | Silent (SNP) | VAF 40/196 reads (20%) | catalogued as rs1295672839, COSV99401489; called by muse, mutect2, varscan2
- TMEM167A | c.135G>A p.K45= | Silent (SNP) | VAF 30/222 reads (14%) | called by muse, mutect2, varscan2
- ZNF579 | c.225G>A p.P75= | Silent (SNP) | VAF 4/15 reads (27%) | called by muse, mutect2, varscan2
- JAZF1-AS1 | n.1037T>C | RNA (SNP) | VAF 6/22 reads (27%) | catalogued as rs572164952; called by muse, mutect2, varscan2
- MED25 | chr19:49838756 G>A | 3'Flank (SNP) | VAF 9/132 reads (7%) | catalogued as rs1210584550; called by muse, mutect2
- NOP2 | c.475-227T>C | Intron (SNP) | VAF 10/173 reads (6%) | catalogued as rs1246954241, COSV59110776; called by muse, mutect2
- SEPSECS | c.115-545C>T | Intron (SNP) | VAF 5/33 reads (15%) | called by mutect2, varscan2
- TMEM135 | c.*6217T>G | 3'UTR (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2
- TMEM78 | n.468T>C | RNA (SNP) | VAF 4/24 reads (17%) | called by mutect2, varscan2
- TPRX2P | n.678G>C | RNA (SNP) | VAF 21/94 reads (22%) | called by muse, mutect2, varscan2
- VAC14 | c.1160+3194A>G | Intron (SNP) | VAF 6/42 reads (14%) | catalogued as rs1210087954; called by muse, mutect2
